CCDI case PBBLMB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/7f501972-c08b-44c8-846e-974d265f0f0b

Demographics
Sex at birth: male.

Diagnoses (1)
1. Schwannoma, NOS: ICD-O-3 morphology code: 9560/0; Tissue or organ of origin: Spinal cord; Age at diagnosis: 14.3 years (5,213 days).

Biospecimens (3 samples)
- Sample 0DBZ51: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBZ5C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DBZ5D: Tissue type: Tumor; Specimen type: Solid Tissue.
